Surgical pathology report (de-identified scan), TCGA case TCGA-CN-6989, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-CN-6989-01A (Primary Tumor).

[page 1 of 6]
Pathology Report [REDACTED] **CORRECTED**

Report Type Pathology Report

Date of Event ... [REDACTED]

Sex M

Authored by [REDACTED]

Hosp/Group [REDACTED]

Record Status CORRECTED

ADDENDA:

Addendum

Part 3: Immunostains for p53 and Ki-67 are not increased in the squamoproliferative areas.

Pathologist: [REDACTED]

**** Report Electronically Signed Out ****

By Pathologist: [REDACTED]

My signature is attestation that I have personally reviewed the submitted material(s) and the above diagnosis reflects that evaluation.

FINAL DIAGNOSIS:

PART 1: LYMPH NODES, RIGHT NECK, LEVELS 2,3 AND 4, SELECTIVE DISSECTION

A. METASTATIC SQUAMOUS CELL CARCINOMA IN FIFTEEN OF NINETEEN LYMPH NODES (LEVELS 2-4), LARGEST METASTASIS: 1.5 CM (level 3)(15/19).

B. EXTRANODAL EXTENSION PRESENT

PART 2: LYMPH NODES, LEFT NECK, LEVELS 2, 3 AND 4, SELECTIVE DISSECTION

A. METASTATIC SQUAMOUS CELL CARCINOMA IN THREE OF THIRTY-SEVEN LYMPH NODES (LEVELS 2-3), LARGEST METASTASIS: 0.7 CM (level 2)(3/37).

B. NO EXTRANODAL EXTENSION PRESENT

PART 3: TONGUE, BASE LEFT, EXCISION

SQUAMOPROLIFERATIVE LESION WITH KERATOSIS, NO CARCINOMA PRESENT (see comment)

PART 4: PHARYNX, LEFT LATERAL, EXCISION

NO TUMOR PRESENT.

PART 5: LARYNX, TOTAL LARYNGECTOMY

A. INVASIVE SQUAMOUS CELL CARCINOMA, MODERATELY DIFFERENTIATED, RIGHT "MARGINAL" SUPRAGLOTTIC/HYPOPHARYNGEAL (4.0 CM) EXTENDING INTO PRE-EPIGLOTTIC SOFT TISSUE.

B. ANGIOLYMPHATIC AND PERINEURAL INVASION PRESENT.

C. PATHOLOGIC STAGE: pT3 N2c

D. INVASIVE SQUAMOUS CELL CARCINOMA, MODERATELY DIFFERENTIATED, LEFT GLOTTIC (1.0CM).

E. PATHOLOGIC STAGE: pT1

F. FINAL MARGINS FREE (SEE ALSO PARTS 3-4,6)

G. UNREMARKABLE THYROID TISSUE

PART 6: TONGUE, RIGHT BASE, EXCISION

NO TUMOR PRESENT.

COMMENT:

Part 3: This part was also reviewed by Dr. [REDACTED] who agrees that there is no carcinoma present. Immunohistochemical stains, P53 and Ki67, will be reported as an addendum.

[page 2 of 6]
Pathologist: [REDACTED]
** Report Electronically Signed Out **
By Pathologist: [REDACTED]
[REDACTED]

My signature is attestation that I have personally reviewed the submitted material(s) and the final diagnosis reflects that evaluation.

GROSS DESCRIPTION:

The specimen is received fresh in six parts.

Part 1 is received labeled with the patient's name, initials XX and "right neck dissection, levels 2, 3 and 4, stitch at 2B". The specimen consists of a segment of fibroadipose tissue measuring 10.0 x 7.0 x 1.0 cm. There is a surgical stitch in one of the extremities of the specimen. Upon section, at level 2, eight possible lymph nodes were identified. At level 3, ten lymph nodes were identified the largest one measures 2.5 x 1.5 x 1.0 cm. At level 4 no grossly visible lymph nodes were identified. The specimen is submitted as follows:

1A-1B - level 2 lymph nodes

1C - level 3 lymph node bisected

1D-1F - level 3 lymph nodes

1G-1H - level 4 soft tissue with possible lymph nodes.

Part 2 is received labeled with the patient's name, initials XX and "left neck dissection, levels 2, 3 and 4, stitch at level 2B". The specimen consists of a segment of yellow soft tissue measuring 12.0 x 5.5 x 1.0 cm. Upon section, 11 lymph nodes were identified in level 2; eight lymph nodes were identified in level 3 and 10 lymph nodes were identified in level 4. The specimen is submitted as follows:

2A-2C - level 2 lymph nodes

2D-2E - level 3 lymph nodes

2F-2H - level 4 lymph nodes.

Part 3 is received labeled with the patient's name, initials XX and "base of left tongue, clip is medial". The specimen was previously submitted intraoperative evaluation. It consists of a 2.0 x 0.5 x 0.5 cm of white firm tissue. The specimen is entirely submitted in cassette 3A (frozen section).

Part 4 is received labeled with the patient's name, initials XX and "left lateral pharynx". The specimen was previously submitted for intraoperative diagnosis. The specimen consists of a 1.0 x 0.5 x 0.3 cm segment of soft, yellow tissue. The specimen is entirely submitted in cassette 4A (frozen section).

Part 5 is received labeled with the patient's name, initials XX and "larynx".

The specimen consists of a total laryngectomy measuring 10.5 x 6.5 x 4.5 cm, including the hyoid bone 2.0 cm on the right side and 0.5 cm on the left side; the larynx from the epiglottis to infraglottic and one tracheal ring.

There is an ulcerated exophytic mass measuring 4x3x2cm located in the supraglottis, base of the tongue involving the lateral wall, the right side of the epiglottis and the soft tissue surrounding the epiglottis. The lesion comes within 1.0 cm from the right false vocal cord. A rough, irregular 1.0 x 0.5 cm area is also identified in the left true vocal cord. The specimen is serially sectioned and submitted as follows:

5A - frozen section right base of tongue

5B - frozen section right lateral pharynx mucosal margin

5C - frozen section soft tissue base of the tongue, perpendicular margin

5D - tracheal margin

5E - tumor

5F - pyriform sinus, left side

5G - epiglottis and tumor right side

[page 3 of 6]
5H - epiglottis tumor, deep margin
5I - tumor and false vocal cord right
5J - false vocal cord, right
5K - left false vocal cord
5L - irregular area in the left true vocal cord
5M - pyriform sinus right side
5N - soft tissue posterior
5O - left side possible lymph nodes
5P - right side possible lymph nodes.

Ink code:

Black: soft tissue

Red: hyoid bone location.

Part 6 is received labeled with the patient's name, initials XX and "right base of tongue, soft tissue margin excision". The specimen consists of a 2.0 x 1.5 x 0.3 cm of soft yellow tissue with small areas of hemorrhage. The specimen is entirely submitted in cassette 6A.

Grossed by: [REDACTED]

INTRAOPERATIVE CONSULTATION:

3AFS: LEFT BASE OF TONGUE (frozen section)

- A. SUFFICIENT FOR ANCILLARY STUDIES.
- B. BENIGN.
- C. NO TUMOR SEEN ([REDACTED]).

4AFS: LEFT LATERAL PHARYNX (frozen section)

- A. SUFFICIENT FOR ANCILLARY STUDIES.
- B. BENIGN.
- C. NO TUMOR SEEN ([REDACTED]).

5AFS: RIGHT BASE OF TONGUE, MUCOSAL MARGIN (frozen section)

- A. SUFFICIENT FOR ANCILLARY STUDIES.
- B. BENIGN.
- C. NO TUMOR SEEN ([REDACTED]).

5BFS: RIGHT LATERAL PHARYNX, MUCOSAL MARGIN, SHAVED (frozen section)

- A. SUFFICIENT FOR ANCILLARY STUDIES.
- B. BENIGN.
- C. NO TUMOR SEEN ([REDACTED]).

5CFS: SOFT TISSUE, BASE OF TONGUE, PERPENDICULAR MARGIN (frozen section)

- A. SUFFICIENT FOR ANCILLARY STUDIES.
- B. MALIGNANT.
- C. INVASIVE SQUAMOUS CELL CARCINOMA, 0.4 CM FROM THE SOFT TISSUE BASE OF THE TONGUE MARGIN ([REDACTED]).

MICROSCOPIC:

Microscopic examination substantiates the above diagnosis.

The following statement applies to all immunohistochemistry, Insitu Hybridization Assays (ISH & FISH), Molecular Anatomic Pathology, and Immunofluorescent Testing:

The testing was developed and its performance characteristics determined by the [REDACTED] Department of Pathology, as required by the CLIA [REDACTED] regulations. The testing has not been cleared or approved for the specific use by the U.S. Food and Drug Administration, but the FDA has determined such approval is not necessary for clinical use. Tissue fixation ranges from a minimum of 2 to a maximum of 84 hours.

This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] ("CLIA") as qualified to perform high-complexity clinical testing. Pursuant to the requirements of CLIA, ASR's used in this laboratory

[page 4 of 6]
have been established and verified for accuracy and precision. Additional information about this type of test is available upon request.

CASE SYNOPSIS:

SYNOPTIC DATA - LARYNX RESECTIONS

TYPE OF LARYNGECTOMY: Total

TUMOR LATERALITY: Right

ATTACHED STRUCTURES: Neck dissection, Pyriform sinus

TUMOR LOCATION/SEGMENT: Supraglottic

TUMOR SIZE: Maximum dimension: 4.0 cm

HISTOLOGIC TYPE OF TUMOR: Squamous cell carcinoma

HISTOLOGIC GRADE: Moderately differentiated

STRUCTURES INVOLVED BY TUMOR: Epiglottis, Extralaryngeal soft tissue

LYMPH NODES: Lymph nodes positive, Right: 15

Total number of right sided lymph nodes examined: 19

Lymph nodes positive, Left: 3

Total number of left sided lymph nodes examined: 37

EXTRACAPSULAR SPREAD OF LYMPH NODE METASTASES

Yes

INTRA-PERINEURAL INVASION: Present

VASCULAR INVASION: Yes

SURGICAL MARGIN INVOLVEMENT: Free (2 mm or more)

TNM DESCRIPTORS: m

T STAGE, PATHOLOGIC: Supraglottis, pT3

N STAGE, PATHOLOGIC: pN2c

M STAGE, PATHOLOGIC: pMX

SYNOPTIC DATA - LARYNX RESECTIONS

TYPE OF LARYNGECTOMY: Total

TUMOR LATERALITY: Left

ATTACHED STRUCTURES: Neck dissection, Pyriform sinus, Base of tongue

TUMOR LOCATION/SEGMENT: Glottic

TUMOR SIZE: Maximum dimension: 1.0 cm

HISTOLOGIC TYPE OF TUMOR: Squamous cell carcinoma

HISTOLOGIC GRADE: Moderately differentiated

STRUCTURES INVOLVED BY TUMOR: True cord

LYMPH NODES: Lymph nodes positive, Right: 15

Total number of right sided lymph nodes examined: 19

Lymph nodes positive, Left: 3

Total number of left sided lymph nodes examined: 37

EXTRACAPSULAR SPREAD OF LYMPH NODE METASTASES

Yes

INTRA-PERINEURAL INVASION: Absent

VASCULAR INVASION: No

SURGICAL MARGIN INVOLVEMENT: Free (2 mm or more)

TNM DESCRIPTORS: m

T STAGE, PATHOLOGIC: Glottis, pT1a

N STAGE, PATHOLOGIC: pNX

M STAGE, PATHOLOGIC: pMX

Comment: mets are likely from the other primary

PATIENT HISTORY:

CHIEF COMPLAINT/ PRE-OP/ POST-OP DIAGNOSIS: Malignant neoplasm pharynx.

PROCEDURE: Bilateral neck dissection, total laryngectomy.

BIOHAZARD: Yes, MRSA.

SPECIFIC CLINICAL QUESTION: Not given.

[page 5 of 6]
OUTSIDE TISSUE DIAGNOSIS: Not given.
PRIOR MALIGNANCY: Not given.
CHEMORADIATION THERAPY: Not given.
ORGAN TRANSPLANT: Not given.
IMMUNOSUPPRESSION: Not given.
OTHER DISEASES: Not given.
CYTOGENETICS TESTS: Not given.

HISTO TISSUE SUMMARY/SLIDES REVIEWED:

Part 1: Right Neck Dissection Level 2-4

Taken: [REDACTED] Received: [REDACTED]

Stain/cnt Block

H&E x 1 A

H&E x 1 B

H&E x 1 C

H&E x 1 D

H&E x 1 E

H&E x 1 F

H&E x 1 G

H&E x 1 H

Part 2: Left Neck Dissection Level 2-4

Taken: [REDACTED] Received: [REDACTED]

Stain/cnt Block

H&E x 1 A

H&E x 1 B

H&E x 1 C

H&E x 1 D

H&E x 1 E

H&E x 1 F

H&E x 1 G

H&E x 1 H

Part 3: Base Left of Tongue

Taken: [REDACTED] Received: [REDACTED]

Stain/cnt Block

ANEG x 1 AFS

RHHE Lev ____ x 1 AFS

RHHE Lev ____ x 1 AFS

RHHE Lev ____ x 1 AFS

RHHE Lev ____ x 1 AFS

RHHE Lev ____ x 1 AFS

H&E x 1 AFS

KI67 x 1 AFS

P53 x 1 AFS

Part 4: Left Lateral Pharynx

Taken: [REDACTED] Received: [REDACTED]

Stain/cnt Block

H&E x 1 AFS

Part 5: Larynx

Taken: [REDACTED] Received: [REDACTED]

Stain/cnt Block

H&E x 1 D

H&E x 1 E

H&E x 1 F

H&E x 1 G

H&E x 1 H

H&E x 1 I

[page 6 of 6]
H&E x 1 J

H&E x 1 K

H&E x 1 L

H&E x 1 M

H&E x 1 N

H&E x 1 O

H&E x 1 P

H&E x 1 AFS

H&E x 1 BFS

H&E x 1 CFS

Part 6: Right Base of Tongue

Taken: [REDACTED] Received: [REDACTED]

Stain/cnt Block

H&E x 1 A

CONSULTING PATHOLOGIST(S): [REDACTED]

TC1

Source: NCI Genomic Data Commons file bfd8dd50-da2b-4cd9-8571-292cb36ece6b (TCGA-CN-6989.312318E0-D06D-4D98-A319-57F0D3201421.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).